Somatic mutation profile of tumor specimen TCGA-EB-A41A-01A (aliquot TCGA-EB-A41A-01A-11D-A24R-08) from TCGA case TCGA-EB-A41A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-EB-A41A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f9e316e-bd17-4af7-a7b3-95fbaa57e97e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A41A-10A (Blood Derived Normal), aliquot TCGA-EB-A41A-10A-01D-A24R-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d01f22f8-bc82-40b2-93ce-a4423cfe3fd6

The open-access MAF lists 2,253 somatic variants for this specimen: 1,468 protein-altering or splice-affecting, 731 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,334, Silent 731, Nonsense Mutation 86, Splice Site 24, Intron 24, RNA 18, Splice Region 11, 3'Flank 7, Frame Shift Del 7, Frame Shift Ins 5, 3'UTR 2, 5'Flank 2.

Variants (750 of 2,253; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CYP2C8 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV64876179; called by muse, mutect2, varscan2
- GBA | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as rs121908309, CM940811, CX165705, COSV59169115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4066G>A p.E1356K | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs727503246, CM042422, CM1313302, COSV62515965; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 52/136 reads (38%) | hotspot (GDC flag); catalogued as rs778405030, CM950845, COSV62197118; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SFRP4 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as rs755007671, COSV71412681; ClinVar: pathogenic; called by muse, varscan2
- A4GALT | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs746341100, COSV50746147; called by muse, mutect2, varscan2
- ABCA4 | c.5313-1G>A p.X1771_splice | Splice Site (SNP) | VAF 73/247 reads (30%) | catalogued as COSV64677805; called by muse, mutect2, varscan2
- ABCA4 | c.3803C>T p.P1268L | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV64677809; called by muse, mutect2, varscan2
- ABCA4 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV64674407; called by muse, mutect2, varscan2
- ABCC1 | c.3074C>T p.S1025L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.019); catalogued as rs1308578698, COSV60693644; called by muse, mutect2, varscan2
- ABCC12 | c.3202G>T p.G1068* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as COSV60916789, COSV60918122; called by muse, mutect2, varscan2
- ABCC12 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60918127; called by muse, mutect2, varscan2
- ABCC3 | c.2114T>G p.L705R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53328644; called by muse, mutect2, varscan2
- ABCC6 | c.4102G>A p.D1368N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52747665; called by muse, mutect2, varscan2
- ABCC6 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV52745919; called by muse, mutect2, varscan2
- ABCC6 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52747676; called by muse, mutect2, varscan2
- ABCC6 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770532500, CM091244, COSV52745281; called by muse, mutect2, varscan2
- ABCD2 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV58050806; called by muse, mutect2, varscan2
- ABCG1 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59210222; called by muse, mutect2, varscan2
- ACACB | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.701); catalogued as rs759694366, COSV58145648; called by muse, mutect2, varscan2
- ACADS | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV54369467; called by muse, mutect2, varscan2
- ACD | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs868651125, COSV54666888; called by muse, mutect2, varscan2
- ACHE | c.1554G>A p.G518= | Splice Region (SNP) | VAF 21/45 reads (47%) | catalogued as rs773254333, COSV53821388; called by muse, mutect2, varscan2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2, varscan2
- ACSM5 | c.204+2T>G p.X68_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as COSV59374714; called by muse, mutect2, varscan2
- ACSM6 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58980691; called by muse, mutect2, varscan2
- ACSS3 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54100861; called by muse, mutect2, varscan2
- ACTL7B | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1468169591, COSV101012556; called by muse, mutect2, varscan2
- ACTR6 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs142634632; called by muse, mutect2, varscan2
- ACTR8 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51638433; called by muse, mutect2, varscan2
- ADAM18 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs865870698, COSV55844130; called by muse, mutect2, varscan2
- ADAM20 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV56456519, COSV99833610; called by muse, mutect2, varscan2
- ADAM23 | c.1853-1G>A p.X618_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100008281, COSV52220288; called by muse, mutect2
- ADAM29 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.29); catalogued as rs1279168247, COSV63659947; called by muse, mutect2, varscan2
- ADAMTS18 | c.3218G>A p.R1073K | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV51422876; called by muse, mutect2, varscan2
- ADAMTS18 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 98/261 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99273578; called by mutect2, varscan2
- ADAMTS19 | c.908T>A p.I303N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); catalogued as COSV50795652, COSV50798314; called by muse, mutect2, varscan2
- ADAMTS20 | c.4571G>A p.R1524Q | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs757394006, COSV67138793; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs752320454, COSV99720080; called by muse, varscan2
- ADAMTSL3 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs757818243, COSV54445881, COSV99720086; called by muse, varscan2
- ADAMTSL3 | c.4607G>A p.R1536K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as COSV54436758, COSV54468421; called by muse, mutect2, varscan2
- ADARB1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs772897635, COSV62342045; called by muse, mutect2, varscan2
- ADCY2 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57898693; called by muse, mutect2, varscan2
- ADGRB3 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV65418628; called by muse, mutect2, varscan2
- ADGRB3 | c.4405C>T p.P1469S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as COSV53253055, COSV53259530; called by muse, mutect2, varscan2
- ADGRD1 | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as COSV55456714; called by muse, mutect2
- ADGRF4 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51950045, COSV51951782; called by muse, mutect2, varscan2
- ADGRG4 | c.2501G>A p.R834K | Missense Mutation (SNP) | VAF 81/95 reads (85%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54952827, COSV54966312; called by muse, mutect2, varscan2
- ADGRG4 | c.6638C>T p.S2213L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs758228443, COSV54966327; called by muse, mutect2, varscan2
- ADGRL4 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66065703; called by muse, mutect2, varscan2
- ADGRV1 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV67994862; called by muse, mutect2, varscan2
- ADGRV1 | c.10882C>T p.P3628S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs564470089, COSV67988859; ClinVar: uncertain significance; called by muse, mutect2
- ADGRV1 | c.12109G>A p.E4037K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV67994866; called by muse, mutect2, varscan2
- ADH7 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs549028723, COSV52923136; called by muse, mutect2, varscan2
- ADORA2A | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs773743606, COSV58380590; called by muse, mutect2, varscan2
- ADRB3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353983568, COSV61462615; called by muse, mutect2, varscan2
- AEBP1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56261135; called by muse, mutect2, varscan2
- AGMAT | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65435832; called by muse, mutect2, varscan2
- AHNAK2 | c.12916C>T p.P4306S | Missense Mutation (SNP) | VAF 180/249 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60929657; called by muse, mutect2, varscan2
- AHSG | c.434T>G p.V145G | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56609348; called by muse, mutect2, varscan2
- AIFM3 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV53151531; called by muse, mutect2, varscan2
- AIMP2 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56151973; called by muse, mutect2, varscan2
- AK9 | c.5374C>T p.P1792S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV69853254; called by muse, mutect2, varscan2
- AKAP5 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs770240917, COSV57743031; called by muse, mutect2, varscan2
- AKAP6 | c.3485C>T p.P1162L | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV55232512; called by muse, mutect2, varscan2
- AKR1B10 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs148486050, COSV62055186; called by muse, mutect2, varscan2
- ALDH1L1 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767684111, COSV56419081; called by muse, mutect2, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALG5 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.074); catalogued as rs781408999, COSV53504840; called by muse, mutect2, varscan2
- ALOX5 | c.153G>A p.V51= | Splice Region (SNP) | VAF 24/71 reads (34%) | catalogued as COSV65554332; called by muse, mutect2, varscan2
- ALPP | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.959); catalogued as COSV67397955; called by muse, mutect2, varscan2
- AMTN | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs773335972, COSV59490186; called by muse, mutect2, varscan2
- AMY2B | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 172/334 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.237); catalogued as rs550567671, COSV100796408; called by muse, mutect2, varscan2
- ANAPC4 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1450004796, COSV59543235; called by muse, mutect2, varscan2
- ANK3 | c.3031C>T p.P1011S (on ENST00000280772 / NM_001320874.2; = p.P145S on NM_001149.3) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55080242; called by muse, mutect2, varscan2
- ANK3 | c.1694G>A p.G565E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867615351, COSV55080279; called by muse, mutect2, varscan2
- ANK3 | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV55080299; called by muse, mutect2, varscan2
- ANKRD12 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV50847151; called by muse, mutect2, varscan2
- ANKRD28 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs771789757, COSV67520020; called by muse, mutect2, varscan2
- ANKRD44 | c.2131-1G>C p.X711_splice | Splice Site (SNP) | VAF 55/138 reads (40%) | catalogued as COSV56565611; called by muse, varscan2
- ANO2 | c.643G>A p.G215R (on ENST00000356134 / NM_001278597.3; = p.G219R on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV59042263; called by muse, mutect2, varscan2
- ANO4 | c.2122G>A p.G708R (on ENST00000392977 / NM_001286615.2; = p.G673R on NM_178826.4) | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54589748; called by muse, mutect2, varscan2
- ANO4 | c.2338C>T p.L780F (on ENST00000392977 / NM_001286615.2; = p.L745F on NM_178826.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV54592579, COSV54594505; called by muse, mutect2, varscan2
- ANXA10 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63740351; called by muse, mutect2, varscan2
- AP002512.3 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54405398; called by muse, mutect2, varscan2
- APCS | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866542574, COSV54818126; called by muse, mutect2, varscan2
- APOB | c.10492G>A p.G3498R | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51951428; called by muse, mutect2, varscan2
- ARAP2 | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58282016, COSV58291868; called by muse, mutect2, varscan2
- ARFGAP2 | c.1549C>T p.R517C | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs11542794, COSV53569913; called by muse, mutect2, varscan2
- ARHGAP30 | c.2524G>A p.D842N | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs1557914315, COSV63519212; called by muse, mutect2, varscan2
- ARHGAP30 | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100920388, COSV63518889; called by muse, mutect2, varscan2
- ARHGEF12 | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63104996, COSV63105882, COSV63107238; called by muse, mutect2, varscan2
- ARHGEF5 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1304459555, COSV99283012; called by mutect2, varscan2
- ARHGEF5 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV99283016; called by mutect2, varscan2
- ARID2 | c.2567C>T p.T856I | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV57614190; called by muse, mutect2, varscan2
- ARID2 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1272432698, COSV57614196; called by muse, mutect2, varscan2
- ARL11 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56292110; called by muse, mutect2, varscan2
- ARL15 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72292703; called by muse, mutect2, varscan2
- ARMC4 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV100537232, COSV59473390; called by muse, mutect2, varscan2
- ARMC4 | c.1239G>A p.R413= | Splice Region (SNP) | VAF 23/73 reads (32%) | catalogued as rs765937444, COSV53468351; called by muse, mutect2, varscan2
- ARMC6 | c.151C>T p.P51S (on ENST00000392336; = p.P26S on NM_033415.4) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1163040715, COSV54184111; called by muse, mutect2, varscan2
- ARNT | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV62229775; called by muse, mutect2, varscan2
- ARRDC2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.446); catalogued as COSV55844066; called by muse, mutect2, varscan2
- ARSJ | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs773039894, COSV59539747; called by muse, mutect2, varscan2
- ART3 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as rs771499381, COSV61915134; called by muse, mutect2, varscan2
- ASAH2 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 183/439 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs781198700; called by muse, mutect2, varscan2
- ASTN1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV56076232; called by muse, mutect2, varscan2
- ASXL3 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 81/131 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV52460796; called by muse, mutect2, varscan2
- ASXL3 | c.5672G>A p.S1891N | Missense Mutation (SNP) | VAF 240/370 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV52478994; called by muse, mutect2, varscan2
- ATF6B | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV64352618; called by muse, mutect2, varscan2
- ATP10B | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as rs752876552, COSV58781238; called by muse, mutect2, varscan2
- ATP13A4 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61326811; called by muse, mutect2, varscan2
- ATP1A3 | c.1148C>T p.T383I (on ENST00000545399 / NM_001256214.2; = p.T370I on NM_152296.5) | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM142782, COSV57491131; called by muse, mutect2, varscan2
- ATP2B4 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV58183609; called by muse, mutect2, varscan2
- ATP6V1C2 | c.68A>C p.N23T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV55364837; called by muse, mutect2, varscan2
- ATP9A | c.2019T>C p.V673= | Splice Region (SNP) | VAF 5/99 reads (5%) | catalogued as COSV58772694; called by muse, mutect2
- AZU1 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52142548; called by muse, mutect2, varscan2
- B3GALT1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs144099662, COSV59908175; called by muse, mutect2, varscan2
- BAAT | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52290930; called by muse, mutect2, varscan2
- BAHCC1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as rs782241889, COSV57033002; called by muse, mutect2, varscan2
- BANK1 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV59849616; called by muse, mutect2, varscan2
- BARX2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55652376; called by muse, mutect2, varscan2
- BCAT1 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV53917394; called by muse, mutect2, varscan2
- BCAT2 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1473516504, COSV60274066; called by muse, mutect2, varscan2
- BCL11A | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.696); catalogued as rs767926301, COSV100186100; called by muse, mutect2, varscan2
- BCOR | c.2143A>T p.T715S | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV60717963, COSV60720278; called by muse, mutect2, varscan2
- BEND2 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 86/104 reads (83%) | catalogued as COSV66221727; called by muse, mutect2, varscan2
- BHMT | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57155686; called by muse, mutect2
- BIRC6 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV70205544; called by muse, mutect2, varscan2
- BIRC6 | c.2223C>A p.D741E | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428644, COSV70200606, COSV70205550; called by muse, mutect2, varscan2
- BMP3 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51082144; called by muse, mutect2, varscan2
- BMP5 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV100895861, COSV63706400; called by muse, mutect2, varscan2
- BMP5 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.895); catalogued as COSV63702143; called by muse, mutect2, varscan2
- BNC2 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs565251984, COSV66142337; called by muse, mutect2, varscan2
- BPIFB4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs140887073; called by muse, mutect2, varscan2
- BRAT1 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV61397316; called by muse, mutect2, varscan2
- BRCA1 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as CD086715, COSV58799055; called by muse, mutect2, varscan2
- BRD8 | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54732020; called by muse, mutect2, varscan2
- BRINP3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367902400, COSV66524676; called by muse, mutect2, varscan2
- BSCL2 | c.719C>A p.A240D | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV99628384; called by muse, mutect2, varscan2
- BSCL2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99627967; called by muse, mutect2, varscan2
- BSN | c.6911G>A p.G2304E | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.397); catalogued as COSV56526924; called by muse, mutect2, varscan2
- BTBD11 | c.1481A>G p.Q494R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs909065596, COSV55036930; called by muse, mutect2, varscan2
- BUB1 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs867863036, COSV57062533; called by muse, mutect2, varscan2
- C10orf120 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as rs868856614, COSV61491793, COSV61492605; called by muse, mutect2, varscan2
- C12orf40 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61137556; called by muse, mutect2, varscan2
- C12orf54 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs370792737, COSV58360570; called by muse, mutect2, varscan2
- C1R | c.1840G>A p.E614K (on ENST00000536053 / NM_001354346.2; = p.E600K on NM_001733.7) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV73383055; called by muse, mutect2, varscan2
- C22orf31 | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 74/93 reads (80%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as COSV53311208, COSV99326314; called by muse, mutect2, varscan2
- C2orf78 | c.2651G>A p.R884K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs756025346, COSV101280906, COSV68519290; called by muse, mutect2, varscan2
- C3orf38 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756172749, COSV59627510; called by muse, mutect2, varscan2
- C4BPA | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV65536059; called by muse, mutect2, varscan2
- C4orf17 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as COSV58513544; called by muse, mutect2, varscan2
- C6orf58 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.635); catalogued as COSV61666010; called by muse, mutect2, varscan2
- C7 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57471459; called by muse, mutect2, varscan2
- C8B | c.1138A>G p.K380E | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV64779559; called by muse, mutect2, varscan2
- C8orf34 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV61396066; called by muse, mutect2, varscan2
- C8orf34 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748608422, COSV57412574; called by muse, varscan2
- C8orf34 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV57398183; called by muse, varscan2
- CACNA1E | c.5957C>T p.P1986L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV62419367; called by muse, mutect2, varscan2
- CACNA1E | c.6404C>T p.T2135I (on ENST00000367573 / NM_001205293.3; = p.T2092I on NM_000721.4) | Missense Mutation (SNP) | VAF 106/189 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs376304436; called by muse, mutect2, varscan2
- CACNA2D3 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV55549781, COSV55580362; called by muse, mutect2, varscan2
- CAD | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53031625; called by muse, mutect2, varscan2
- CALCRL | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs762193098, COSV66477320; called by muse, mutect2, varscan2
- CALML4 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61206244; called by muse, mutect2, varscan2
- CAMTA2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV61838141; called by muse, mutect2, varscan2
- CAPN15 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 88/113 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54839438; called by muse, mutect2, varscan2
- CASR | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56137519; called by muse, varscan2
- CASR | c.2476G>A p.G826R (on ENST00000490131; = p.G903R on NM_000388.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56141258; called by muse, mutect2, varscan2
- CATSPER1 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.527); catalogued as COSV56413331; called by muse, mutect2, varscan2
- CATSPERD | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs745670557, COSV58465097; called by muse, mutect2, varscan2
- CAVIN2 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 98/246 reads (40%) | catalogued as rs746573358, COSV58425804; called by muse, mutect2, varscan2
- CBL | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV50662640; called by muse, mutect2, varscan2
- CCDC102B | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 65/189 reads (34%) | catalogued as rs186843401, COSV60140682; called by muse, mutect2, varscan2
- CCDC114 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV59558662; called by muse, mutect2, varscan2
- CCDC151 | c.143G>A p.W48* | Nonsense Mutation (SNP) | VAF 43/97 reads (44%) | catalogued as COSV52954000; called by muse, mutect2, varscan2
- CCDC158 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.879); catalogued as COSV66356475; called by muse, mutect2, varscan2
- CCDC158 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66355394, COSV66357160; called by muse, mutect2, varscan2
- CCDC181 | c.1460C>T p.S487F (on ENST00000367806 / NM_001300969.1; = p.S486F on NM_021179.2) | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV61394863; called by muse, mutect2, varscan2
- CCDC181 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs144603502, COSV63158073; called by muse, mutect2, varscan2
- CCDC184 | c.333C>G p.F111L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.085); catalogued as COSV57252505; called by muse, mutect2, varscan2
- CCER1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV62647792; called by muse, mutect2, varscan2
- CCNB1IP1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs559090444, COSV62303448; called by muse, mutect2, varscan2
- CCR1 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV56122999; called by muse, mutect2, varscan2
- CCR6 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59475036, COSV59476143; called by muse, mutect2, varscan2
- CD163 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV63136357, COSV63136973; called by muse, mutect2, varscan2
- CD1A | c.606G>A p.V202= | Splice Region (SNP) | VAF 72/124 reads (58%) | catalogued as rs886198295, COSV56864221; called by muse, mutect2, varscan2
- CD2 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65643353; called by muse, mutect2, varscan2
- CD209 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV52649423; called by muse, mutect2, varscan2
- CD6 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57842553; called by muse, mutect2, varscan2
- CD96 | c.1666C>T p.P556S (on ENST00000283285 / NM_198196.3; = p.P540S on NM_005816.5) | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.539); catalogued as COSV51922698; called by muse, mutect2, varscan2
- CDC14B | c.1468A>T p.I490F (on ENST00000375241 / NM_033331.4; = p.I451F on NM_003671.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55793762; called by muse, mutect2, varscan2
- CDC20B | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1379606514, COSV57057190; called by muse, mutect2, varscan2
- CDC42EP2 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV54203944; called by muse, mutect2, varscan2
- CDH11 | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV51752619, COSV99217963; called by muse, mutect2, varscan2
- CDH11 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV51764630; called by muse, mutect2, varscan2
- CDH5 | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs369363449; called by muse, mutect2, varscan2
- CDH8 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs761735900, COSV54898545; called by muse, mutect2, varscan2
- CDHR2 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.293); catalogued as COSV56143782; called by muse, mutect2, varscan2
- CDHR2 | c.768+1G>A p.X256_splice | Splice Site (SNP) | VAF 24/69 reads (35%) | catalogued as COSV56143437; called by muse, mutect2, varscan2
- CDHR2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs759818454, COSV56138267, COSV56140432, COSV99991613; called by muse, mutect2, varscan2
- CDIPT | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54889788; called by muse, mutect2, varscan2
- CDK12 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs146621695; called by muse, mutect2, varscan2
- CDK19 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV60453391; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5053C>T p.P1685S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV62577683; called by muse, mutect2, varscan2
- CDKN1A | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1379336902, COSV55191443; called by muse, mutect2, varscan2
- CEACAM21 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV51816465; called by muse, mutect2, varscan2
- CELSR1 | c.3742C>T p.Q1248* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV53099380; called by muse, mutect2
- CELSR2 | c.2701G>A p.A901T | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV54779122; called by muse, mutect2, varscan2
- CENPB | c.1784T>C p.L595P | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV60149582; called by muse, mutect2, varscan2
- CENPC | c.38A>T p.Y13F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56626298; called by muse, mutect2
- CEP104 | c.2314C>T p.H772Y | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65519612; called by muse, mutect2, varscan2
- CEP170 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs979228941, COSV60514506; called by muse, mutect2, varscan2
- CEP192 | c.2948G>A p.S983N | Missense Mutation (SNP) | VAF 83/149 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV58070462; called by muse, mutect2, varscan2
- CEP192 | c.6217C>T p.L2073F | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV58070473; called by muse, mutect2, varscan2
- CEP85 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1193239293, COSV53330660; called by muse, mutect2, varscan2
- CFAP126 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV61369525; called by muse, mutect2, varscan2
- CFAP54 | c.5641G>A p.E1881K | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV61575086; called by muse, mutect2, varscan2
- CFAP54 | c.6713C>T p.P2238L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1177468592, COSV61575093; called by muse, mutect2, varscan2
- CFAP58 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV57212221; called by muse, mutect2, varscan2
- CFAP58 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs746292556, COSV57211513; called by muse, mutect2, varscan2
- CFAP61 | c.3463C>T p.R1155C | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760799543, COSV55646761, COSV99079351; called by muse, mutect2, varscan2
- CFH | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 96/163 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV66413181; called by muse, mutect2, varscan2
- CFHR5 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56824789; called by muse, mutect2, varscan2
- CFLAR | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 44/106 reads (42%) | catalogued as COSV57938768; called by muse, mutect2, varscan2
- CHD7 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.894); catalogued as rs368160678; ClinVar: uncertain significance; called by muse, varscan2
- CHD7 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV101418349; called by muse, mutect2, varscan2
- CHD7 | c.6770C>T p.P2257L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV71114374; called by muse, mutect2, varscan2
- CHRNB1 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs779839761, COSV60142293; called by muse, mutect2, varscan2
- CHRNB3 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV51497729; called by muse, mutect2, varscan2
- CIITA | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as COSV60861937; called by muse, mutect2, varscan2
- CILP | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV56027723; called by muse, mutect2, varscan2
- CLCA4 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 70/110 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV55366472; called by muse, mutect2, varscan2
- CLCN1 | c.1017G>A p.M339I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV58372190; called by muse, mutect2, varscan2
- CLEC17A | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60426849; called by muse, mutect2, varscan2
- CLEC2B | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs776179456, COSV57310194; called by muse, mutect2, varscan2
- CLEC4C | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV63583253; called by muse, mutect2, varscan2
- CLHC1 | c.1625T>A p.V542E | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs947891472, COSV101284921; called by muse, mutect2, varscan2
- CLHC1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV101284922; called by muse, mutect2, varscan2
- CLIP1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56808284, COSV56809690; called by muse, mutect2, varscan2
- CLK2 | c.1202C>T p.P401L (on ENST00000368361 / NM_001294339.2; = p.P400L on NM_003993.4) | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56947353; called by muse, mutect2, varscan2
- CLSTN2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs762725621, COSV71720257, COSV71721587; called by muse, mutect2, varscan2
- CLUH | c.452T>C p.V151A (on ENST00000435359; = p.V189A on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV70930040; called by muse, mutect2, varscan2
- CMYA5 | c.1868C>T p.A623V | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV71409353; called by muse, mutect2, varscan2
- CMYA5 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV71409356; called by muse, mutect2, varscan2
- CMYA5 | c.5564C>T p.S1855L | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs762874276, COSV71406857; called by muse, mutect2, varscan2
- CMYA5 | c.6898G>A p.E2300K | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs764888673, COSV71409361; called by muse, mutect2, varscan2
- CNGB3 | c.806T>A p.L269Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60698022; called by muse, mutect2, varscan2
- CNGB3 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 100/215 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV60685142; called by muse, mutect2, varscan2
- CNKSR1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1474075616, COSV64163387, COSV64164170; called by muse, mutect2, varscan2
- CNKSR1 | c.1642C>T p.H548Y (on ENST00000374253 / NM_001297647.2; = p.H541Y on NM_006314.3) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.361); catalogued as COSV100128458; called by muse, mutect2, varscan2
- CNTN1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636194; called by muse, mutect2, varscan2
- CNTN3 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV55166251, COSV55180654; called by muse, mutect2, varscan2
- CNTNAP5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV70470072; called by muse, mutect2, varscan2
- COL11A2 | c.1684G>A p.G562R (on ENST00000341947 / NM_080680.3; = p.G455R on NM_080679.2) | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59502273; called by muse, mutect2, varscan2
- COL11A2 | c.1279G>A p.E427K (on ENST00000341947 / NM_080680.3; = p.E320K on NM_080679.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV59502285; called by muse, mutect2, varscan2
- COL12A1 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 38/89 reads (43%) | catalogued as COSV59392176; called by muse, mutect2, varscan2
- COL12A1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV59403248; called by muse, mutect2, varscan2
- COL14A1 | c.2063A>C p.E688A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV52867746; called by muse, mutect2, varscan2
- COL14A1 | c.4679G>A p.G1560E | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52867755; called by muse, mutect2, varscan2
- COL14A1 | c.5207G>A p.G1736E | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52860832; called by muse, mutect2, varscan2
- COL15A1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66649040; called by muse, mutect2, varscan2
- COL18A1 | c.2611C>T p.P871S (on ENST00000359759 / NM_130444.3; = p.P636S on NM_030582.4) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100700816; called by muse, mutect2
- COL18A1 | c.2612C>T p.P871L (on ENST00000359759 / NM_130444.3; = p.P636L on NM_030582.4) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV100700817; called by muse, mutect2
- COL1A2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51965828; called by muse, mutect2, varscan2
- COL1A2 | c.2932C>T p.R978C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145633247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL21A1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55156309; called by muse, mutect2, varscan2
- COL3A1 | c.4036C>T p.P1346S | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.572); catalogued as rs867964012, COSV58596158; called by muse, mutect2, varscan2
- COL4A3 | c.2891G>A p.G964E | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59259478; called by muse, mutect2, varscan2
- COL4A4 | c.3742G>A p.G1248R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867439682, CM161117, COSV61636399; called by muse, mutect2, varscan2
- COL5A1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as rs776904091, COSV65665757; called by muse, mutect2, varscan2
- COL6A1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs754384963, COSV62613454; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- COL7A1 | c.3532C>T p.R1178C | Missense Mutation (SNP) | VAF 130/285 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs142991861; called by muse, mutect2, varscan2
- COPA | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs188927828, COSV54109237; called by muse, mutect2, varscan2
- CORIN | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56698998; called by muse, mutect2, varscan2
- CORIN | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as COSV56699006; called by muse, mutect2, varscan2
- CORO2A | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59664864; called by muse, mutect2, varscan2
- CPAMD8 | c.544G>A p.D182N (on ENST00000651564; = p.D135N on NM_015692.5) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768315508, COSV52239613; called by muse, mutect2, varscan2
- CPNE4 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV70199771; called by muse, mutect2, varscan2
- CPSF1 | c.2174G>A p.S725N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV58235522; called by muse, mutect2, varscan2
- CRACDL | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168021661, COSV67408148; called by muse, mutect2, varscan2
- CRB1 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs368152306, CM058356, COSV66328803; called by muse, mutect2, varscan2
- CRB1 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749366098, COSV66333419; called by muse, mutect2, varscan2
- CRB1 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 110/179 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1392028577, COSV100957590, COSV66328587; called by muse, mutect2, varscan2
- CRLF2 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1265666508, COSV67494263; called by muse, mutect2, varscan2
- CROT | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773253678, COSV58973971; called by muse, mutect2, varscan2
- CRYGC | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV56409800; called by muse, mutect2, varscan2
- CSMD1 | c.9863G>A p.R3288K (on ENST00000520002; = p.R3287K on NM_033225.6) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.963); catalogued as COSV59317509, COSV59380457; called by muse, mutect2, varscan2
- CSMD1 | c.5434G>A p.G1812S (on ENST00000520002; = p.G1811S on NM_033225.6) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59380496; called by muse, mutect2, varscan2
- CSMD1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs779131690, COSV68256897; called by muse, mutect2, varscan2
- CSMD1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68179210; called by muse, mutect2, varscan2
- CSMD3 | c.8073T>C p.V2691= | Splice Region (SNP) | VAF 12/31 reads (39%) | catalogued as COSV52311264; called by muse, mutect2, varscan2
- CSMD3 | c.7580C>T p.S2527F (on ENST00000297405 / NM_001363185.1; = p.S2423F on NM_052900.3) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV52231979, COSV99830652; called by muse, mutect2, varscan2
- CSMD3 | c.5784G>A p.W1928* (on ENST00000297405 / NM_001363185.1; = p.W1824* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 40/98 reads (41%) | catalogued as COSV52142901; called by muse, mutect2, varscan2
- CTIF | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV56491399; called by muse, mutect2, varscan2
- CTSO | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70809699; called by muse, mutect2, varscan2
- CUL9 | c.3755T>G p.V1252G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52734412; called by muse, varscan2
- CXCL5 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs563521523, COSV56019154; called by muse, mutect2, varscan2
- CXCR2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59282035; called by muse, mutect2, varscan2
- CXCR4 | c.224A>T p.K75M | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.442); catalogued as COSV54016829; called by muse, mutect2, varscan2
- CXorf21 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 60/71 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66763291; called by muse, mutect2, varscan2
- CYBB | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as CM127701, COSV66086292; called by muse, mutect2, varscan2
- CYP2C19 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs868529134, COSV64907388; called by muse, mutect2, varscan2
- CYP2C19 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as rs375781227, CM097285, COSV64909346; ClinVar: drug response; called by muse, mutect2, varscan2
- CYP39A1 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as rs1199255885, COSV51499122; called by muse, mutect2, varscan2
- CYP39A1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV51499130; called by muse, mutect2
- CYP4F2 | c.117C>G p.Y39* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV50002777; called by muse, mutect2, varscan2
- CYP4X1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64150723; called by muse, mutect2, varscan2
- CYP4Z1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs868399298, COSV61964879; called by muse, mutect2, varscan2
- CYTL1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.36); catalogued as rs137887145, COSV57037313; called by muse, mutect2, varscan2
- DACH1 | c.1742C>T p.S581F (on ENST00000619232 / NM_001366712.1; = p.S327F on NM_004392.6) | Missense Mutation (SNP) | VAF 99/301 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV100499256, COSV57503837; called by muse, mutect2, varscan2
- DAZL | c.834+1G>A p.X278_splice | Splice Site (SNP) | VAF 59/120 reads (49%) | catalogued as COSV51714443; called by muse, mutect2, varscan2
- DBX2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1289926808, COSV60337792; called by muse, mutect2, varscan2
- DCAF8L1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1274514972, COSV71595516; called by muse, mutect2, varscan2
- DCTN4 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV69783069; called by muse, mutect2, varscan2
- DEFB114 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs752246175, COSV59037087; called by muse, mutect2, varscan2
- DEFB124 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.28); catalogued as COSV58343653; called by muse, mutect2, varscan2
- DENND4A | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101475390, COSV71266999; called by muse, varscan2
- DENND5B | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV100172396, COSV60908241; called by muse, mutect2, varscan2
- DGKG | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53962021; called by muse, mutect2
- DGKK | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs373977703, COSV65708353; called by muse, mutect2, varscan2
- DHX8 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 52/117 reads (44%) | catalogued as COSV52256515; called by muse, mutect2, varscan2
- DIAPH1 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as COSV53888513; called by muse, mutect2
- DIDO1 | c.3791C>T p.P1264L | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.73); catalogued as rs757184367, COSV56624423; called by muse, mutect2, varscan2
- DIS3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146500302, COSV66707916; called by muse, mutect2, varscan2
- DLC1 | c.3350G>A p.G1117E (on ENST00000276297 / NM_001348081.2; = p.G680E on NM_006094.5) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52326924; called by muse, mutect2, varscan2
- DLC1 | c.1166A>T p.H389L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs745775316, COSV99364390; called by muse, mutect2, varscan2
- DNAAF1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs781004949, COSV57577788; called by muse, mutect2, varscan2
- DNAH10 | c.1036G>A p.E346K (on ENST00000409039; = p.E285K on NM_207437.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV69001107; called by muse, mutect2, varscan2
- DNAH17 | c.10009C>T p.R3337C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770314546, COSV67760329; called by muse, mutect2, varscan2
- DNAH17 | c.7227G>A p.W2409* | Nonsense Mutation (SNP) | VAF 34/63 reads (54%) | catalogued as COSV67760849; called by muse, mutect2, varscan2
- DNAH2 | c.3850G>A p.E1284K | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV66726820; called by muse, mutect2, varscan2
- DNAH2 | c.10039C>T p.P3347S | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV66719920; called by muse, mutect2, varscan2
- DNAH3 | c.3967C>T p.Q1323* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as rs976007808, COSV54549914; called by muse, mutect2, varscan2
- DNAH3 | c.3332G>A p.R1111K | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV54549937; called by muse, mutect2, varscan2
- DNAH5 | c.12778G>A p.D4260N | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54250547; called by muse, mutect2, varscan2
- DNAH5 | c.10864G>A p.E3622K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV54250560; called by muse, mutect2, varscan2
- DNAH5 | c.9844G>A p.E3282K | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV54223546; called by muse, mutect2, varscan2
- DNAH5 | c.8926G>T p.V2976F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54250588, COSV99456812; called by muse, mutect2, varscan2
- DNAH5 | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371700933; called by muse, mutect2
- DNAH5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs866784113, COSV54205135; called by muse, mutect2, varscan2
- DNAH7 | c.9179G>A p.G3060E | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1559122443, COSV56784836; called by muse, mutect2, varscan2
- DNAH8 | c.7831G>A p.G2611R | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59478868; called by muse, mutect2, varscan2
- DNAH9 | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52346715; called by muse, mutect2, varscan2
- DNAH9 | c.3833C>T p.S1278F | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52375726; called by muse, mutect2, varscan2
- DNAH9 | c.9253G>A p.D3085N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV52375736; called by muse, mutect2, varscan2
- DNMT3B | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV52422601; called by muse, mutect2, varscan2
- DOCK10 | c.5635C>T p.R1879C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1213034885, COSV51350825; called by muse, mutect2, varscan2
- DOCK8 | c.3479C>T p.T1160I | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV66623836; called by muse, mutect2, varscan2
- DOK6 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs1377828332, COSV66937345; called by muse, mutect2
- DPF2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV52891286; called by muse, mutect2, varscan2
- DPP4 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62109654; called by muse, mutect2, varscan2
- DPRX | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV64949962; called by muse, mutect2, varscan2
- DPYD | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as rs267598786, COSV64609998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYD | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60083477; called by muse, mutect2, varscan2
- DQX1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV66353644; called by muse, mutect2, varscan2
- DR1 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64725895; called by muse, mutect2, varscan2
- DSC1 | c.2273A>G p.N758S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs1339306810, COSV57151235; called by muse, mutect2, varscan2
- DSC1 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57151251; called by muse, mutect2, varscan2
- DSC1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs745670805, COSV57141688; called by muse, mutect2, varscan2
- DSC3 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64571535; called by muse, mutect2
- DSCAM | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101260947; called by muse, mutect2, varscan2
- DSCAML1 | c.3904G>A p.E1302K (on ENST00000321322; = p.E1242K on NM_020693.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.829); catalogued as rs1265129879, COSV100354136, COSV58402227; called by muse, mutect2, varscan2
- DSCAML1 | c.2026C>T p.P676S (on ENST00000321322; = p.P616S on NM_020693.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV58402237; called by muse, mutect2, varscan2
- DSCAML1 | c.698G>A p.R233K (on ENST00000321322; = p.R173K on NM_020693.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.646); catalogued as COSV58402245; called by muse, mutect2, varscan2
- DSCAML1 | c.584G>A p.R195K (on ENST00000321322; = p.R135K on NM_020693.4) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.297); catalogued as rs765017890, COSV58402254; called by muse, mutect2, varscan2
- DSG2 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV55202778; called by muse, mutect2, varscan2
- DSG3 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs758453872, COSV57124501; called by muse, mutect2, varscan2
- DSP | c.7426G>A p.E2476K | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65794151, COSV65795768; called by muse, mutect2, varscan2
- DUOX2 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV66534050; called by muse, mutect2, varscan2
- DYNC1I2 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV55529580; called by muse, mutect2, varscan2
- DYNC2H1 | c.9790T>C p.S3264P | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62106280; called by muse, mutect2, varscan2
- EARS2 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71942974; called by muse, mutect2, varscan2
- EBF3 | c.1060G>A p.D354N (on ENST00000355311 / NM_001375392.1; = p.D345N on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV62481570, COSV62482140; called by muse, mutect2, varscan2
- EDC4 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62767337; called by muse, mutect2, varscan2
- EFCAB7 | c.1352A>C p.N451T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as COSV64315331; called by muse, mutect2, varscan2
- EFCC1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV71402168; called by muse, mutect2, varscan2
- EFEMP1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62617821; called by muse, mutect2, varscan2
- EHHADH | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV51627662; called by muse, mutect2, varscan2
- EIF4B | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1381944013, COSV50407637; called by muse, mutect2, varscan2
- EIF5AL1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1290856601; called by mutect2, varscan2
- ELAVL1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV60968855; called by muse, mutect2, varscan2
- ELAVL2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56357799, COSV56358418; called by muse, mutect2, varscan2
- ELOA2 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.535); catalogued as rs780037542, COSV55295431; called by muse, mutect2, varscan2
- EML1 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV51752380; called by muse, mutect2, varscan2
- ENO3 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52779431; called by muse, mutect2, varscan2
- ENOX1 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs765142087, COSV54897670; called by muse, mutect2, varscan2
- ENPEP | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV54457200; called by muse, mutect2, varscan2
- EPAS1 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55390177; called by muse, mutect2, varscan2
- EPHA1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as rs745331095, COSV51976216; called by muse, mutect2, varscan2
- EPHA10 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.847); catalogued as rs752849185, COSV60404110; called by muse, varscan2
- EPHA10 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 86/153 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60405183; called by muse, varscan2
- EPHA2 | c.2369C>T p.S790F | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1194661809, COSV64452882; called by muse, mutect2, varscan2
- EPHA3 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60726479; called by muse, mutect2, varscan2
- EPHA5 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56650826, COSV99901098; called by muse, mutect2, varscan2
- EPHA7 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 47/98 reads (48%) | catalogued as COSV65170482; called by muse, mutect2, varscan2
- EPHB4 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV62269508; called by muse, mutect2, varscan2
- ERC2 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV55602834; called by muse, mutect2, varscan2
- ERN2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs758739777, COSV56831585; called by muse, varscan2
- ERRFI1 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 75/102 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66311295; called by muse, mutect2, varscan2
- ESF1 | c.1007T>C p.L336S | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52524230; called by muse, mutect2, varscan2
- ESYT3 | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56681834; called by muse, mutect2, varscan2
- EXD3 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1002428367, COSV59813331, COSV59814592; called by muse, mutect2, varscan2
- EXO1 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429588689, COSV62219845; called by muse, mutect2, varscan2
- EXPH5 | c.5723G>T p.G1908V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56207995; called by muse, mutect2, varscan2
- EZHIP | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs377184357, COSV100539805; called by muse, mutect2, varscan2
- F13B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 189/304 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV66372079, COSV66375598; called by muse, mutect2, varscan2
- F7 | c.1098G>A p.M366I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as COSV60647987; called by muse, mutect2, varscan2
- F8 | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV64278425; called by muse, mutect2, varscan2
- FADS1 | c.1033A>T p.I345F | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV63521148; called by muse, mutect2, varscan2
- FAM135B | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50526880; called by muse, mutect2, varscan2
- FAM184A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58858640; called by muse, mutect2, varscan2
- FAM219A | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV52622504; called by muse, mutect2, varscan2
- FAM222B | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1359695951; called by muse, mutect2
- FAM234A | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.548); catalogued as rs370881261, COSV56998106; called by muse, mutect2, varscan2
- FAM241B | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV64768823; called by muse, mutect2, varscan2
- FAM47A | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649988, COSV60496687; called by muse, mutect2
- FAM83A | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV52687975; called by muse, mutect2, varscan2
- FAM83B | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs770201088, COSV60921346; called by muse, mutect2
- FAM83B | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.339); catalogued as COSV60920273, COSV60926609; called by muse, mutect2, varscan2
- FAP | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922508798, COSV51867377; called by muse, mutect2, varscan2
- FARP2 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99885058; called by muse, mutect2, varscan2
- FAT3 | c.6674G>A p.G2225E | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs1439191592, COSV53171150; called by muse, mutect2, varscan2
- FAT4 | c.3728G>A p.G1243E | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67899400; called by muse, mutect2, varscan2
- FAT4 | c.11603G>A p.C3868Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1457350696, COSV58707872; called by muse, mutect2, varscan2
- FAT4 | c.13696C>T p.P4566S | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs868630367, COSV58688106; called by muse, mutect2, varscan2
- FBXO15 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs146975565; called by muse, mutect2, varscan2
- FBXO42 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100981863; called by muse, mutect2, varscan2
- FBXW2 | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV61598073; called by muse, mutect2, varscan2
- FCER1A | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 89/347 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs142102904, COSV63667435; called by muse, varscan2
- FCER1A | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV63667126; called by muse, mutect2, varscan2
- FCGBP | c.11939G>A p.R3980Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs746602229; called by muse, mutect2, varscan2
- FCN2 | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs748534479, COSV52478680; called by muse, mutect2, varscan2
- FCRL4 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV54865669; called by muse, mutect2, varscan2
- FCRL5 | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100708763, COSV62519924; called by muse, mutect2, varscan2
- FER1L6 | c.4862C>T p.S1621L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs763858810, COSV67552726; called by muse, mutect2, varscan2
- FES | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs141047785, COSV100183300; called by muse, mutect2, varscan2
- FES | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1243023426, COSV60997677; called by muse, mutect2, varscan2
- FGF20 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51662199; called by muse, mutect2, varscan2
- FGFR2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60658850; called by muse, mutect2, varscan2
- FIG4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747284213, COSV57787058, COSV57787107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FILIP1 | c.3101G>A p.R1034Q | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.434); catalogued as rs531018423, COSV52740282, COSV99384214; called by muse, mutect2, varscan2
- FKBP4 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50009954; called by muse, mutect2, varscan2
- FLG | c.11210C>T p.S3737F | Missense Mutation (SNP) | VAF 443/717 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64248604; called by muse, mutect2, varscan2
- FLG2 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 385/652 reads (59%) | SIFT tolerated (0.9); PolyPhen benign (0.033); catalogued as COSV66173037; called by muse, mutect2, varscan2
- FLG2 | c.2432G>A p.G811E | Missense Mutation (SNP) | VAF 211/731 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as COSV66173049; called by muse, mutect2, varscan2
- FLG2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 121/221 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.234); catalogued as rs778614508, COSV66166513; called by muse, mutect2, varscan2
- FLG2 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 177/276 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1237169705, COSV66173057; called by muse, mutect2, varscan2
- FLG2 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV66173064; called by muse, mutect2, varscan2
- FLNB | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs768316224, COSV55872808; called by muse, mutect2, varscan2
- FLNC | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV57964403; called by muse, mutect2, varscan2
- FLNC | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV57964416; called by muse, mutect2, varscan2
- FLNC | c.7135G>A p.G2379S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57964427; called by muse, mutect2, varscan2
- FLRT3 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150799973; called by muse, mutect2, varscan2
- FMO3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs866502499, COSV63006994; called by muse, mutect2, varscan2
- FNBP4 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs758139997, COSV55452033; called by muse, mutect2, varscan2
- FOXR2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.4); catalogued as rs767845474, COSV59259454, COSV59259611; called by muse, mutect2, varscan2
- FOXR2 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 52/61 reads (85%) | catalogued as COSV59259126, COSV59259694; called by muse, mutect2, varscan2
- FPGS | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64676235; called by muse, mutect2, varscan2
- FRAS1 | c.10519G>T p.D3507Y | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53645705, COSV99354390; called by muse, mutect2, varscan2
- FREM1 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746156557, COSV66526811; called by muse, mutect2, varscan2
- FRMD7 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 77/93 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV53748657; called by muse, mutect2, varscan2
- FRRS1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 122/202 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs755680896, COSV54924260; called by muse, mutect2, varscan2
- FRY | c.8524T>A p.F2842I | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.627); catalogued as COSV66511717; called by muse, mutect2, varscan2
- FRYL | c.7139C>T p.S2380L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51961754; called by muse, mutect2, varscan2
- FSIP2 | c.20382G>A p.M6794I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58099205; called by muse, mutect2, varscan2
- FUT9 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs868515812, COSV100133533, COSV104402639, COSV56144749; called by muse, mutect2, varscan2
- FYB2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs866261983, COSV58583834, COSV58588477; called by muse, mutect2, varscan2
- FYB2 | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 187/301 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV58589111; called by muse, mutect2, varscan2
- G2E3 | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs1037346027, COSV52842778; called by muse, mutect2, varscan2
- GABBR2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.146); catalogued as rs745672188, COSV52318864, COSV99411736; called by muse, mutect2, varscan2
- GABRA3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64802855, COSV64805018; called by muse, mutect2, varscan2
- GABRA3 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64805029; called by muse, mutect2, varscan2
- GABRA6 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50877454; called by muse, mutect2, varscan2
- GAL3ST1 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58893554; called by muse, mutect2, varscan2
- GALNT13 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV67238299; called by muse, mutect2, varscan2
- GALNT14 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV61110947; called by muse, mutect2, varscan2
- GALNT2 | c.1403T>C p.V468A | Missense Mutation (SNP) | VAF 80/364 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.325); catalogued as COSV64197386; called by muse, mutect2, varscan2
- GALNTL5 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs926094593, COSV67179699; called by muse, mutect2, varscan2
- GAREM1 | c.1759C>T p.P587S (on ENST00000269209 / NM_001242409.2; = p.P586S on NM_022751.3) | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV52515773; called by muse, mutect2, varscan2
- GAREM1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV52515781; called by muse, mutect2, varscan2
- GATA5 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV53347397; called by muse, mutect2, varscan2
- GBA3 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72438732; called by muse, varscan2
- GBA3 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV72438737; called by muse, mutect2, varscan2
- GCFC2 | c.1705C>T p.L569F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1417963915, COSV58080685, COSV58083347; called by muse, mutect2, varscan2
- GCSAM | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58264499; called by muse, mutect2, varscan2
- GDPGP1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.051); catalogued as COSV61576115; called by muse, mutect2, varscan2
- GID8 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV56612197; called by muse, mutect2, varscan2
- GJA10 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101005411; called by muse, mutect2, varscan2
- GLDC | c.1225A>T p.R409W | Missense Mutation (SNP) | VAF 102/139 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58684947; called by muse, mutect2, varscan2
- GLI2 | c.2332G>A p.E778K (on ENST00000361492 / NM_001374353.1; = p.E795K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as rs1406444413, COSV58051044; called by muse, mutect2, varscan2
- GLIS2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as rs756890259, COSV52111897; called by muse, mutect2, varscan2
- GLP2R | c.953G>A p.W318* | Nonsense Mutation (SNP) | VAF 57/141 reads (40%) | catalogued as COSV52329382; called by muse, mutect2, varscan2
- GLYATL1 | c.304C>T p.Q102* (on ENST00000317391 / NM_001354699.1; = p.Q133* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as rs895042982, COSV55609314, COSV55611370; called by muse, mutect2, varscan2
- GLYATL2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54851486; called by muse, mutect2, varscan2
- GNAI2 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56493295; called by muse, mutect2, varscan2
- GON4L | c.3286C>T p.P1096S | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.021); catalogued as rs574583931, COSV55203620; called by muse, mutect2, varscan2
- GORASP2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs534480653, COSV52203844; called by muse, mutect2, varscan2
- GP5 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV55469368; called by muse, mutect2, varscan2
- GPR142 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV100170906; called by muse, mutect2, varscan2
- GPR158 | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867635270, COSV66267242; called by muse, mutect2, varscan2
- GRB14 | c.1383-1G>A p.X461_splice | Splice Site (SNP) | VAF 27/68 reads (40%) | catalogued as COSV55743259, COSV99813682; called by muse, mutect2, varscan2
- GRIA1 | c.2522G>A p.G841D | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as COSV53623624; called by muse, mutect2, varscan2
- GRIN2B | c.3315C>G p.I1105M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV74207153, COSV74207698; called by muse, varscan2
- GRIN3B | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52263420; called by muse, mutect2
- GRWD1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as COSV53520181; called by muse, mutect2, varscan2
- GRXCR1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV67674611; called by muse, varscan2
- GSG1L | c.923C>T p.S308F (on ENST00000447459 / NM_001109763.2; = p.S153F on NM_144675.2) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.962); catalogued as rs948840199, COSV66582114; called by muse, mutect2, varscan2
- GUCY2D | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1282252899, COSV54698883; called by muse, mutect2, varscan2
- GZMA | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs776260529, COSV57113676; called by muse, mutect2, varscan2
- HAO2 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58042062; called by muse, mutect2, varscan2
- HBG2 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.832); catalogued as rs1182604197, COSV57963618; called by muse, mutect2, varscan2
- HCFC2 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57560340; called by muse, mutect2, varscan2
- HCN4 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56087161, COSV99983226; called by muse, mutect2, varscan2
- HCRTR2 | c.359G>A p.W120* | Nonsense Mutation (SNP) | VAF 98/332 reads (30%) | catalogued as COSV63798986; called by muse, mutect2, varscan2
- HCRTR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866684522, COSV63795299; called by muse, varscan2
- HCRTR2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV63798993; called by muse, varscan2
- HDAC5 | c.1603C>T p.L535F | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV56821825; called by muse, mutect2, varscan2
- HDAC9 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs1244191603, COSV67784750; called by muse, mutect2, varscan2
- HEATR1 | c.3596T>C p.V1199A | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.022); catalogued as COSV63982956; called by muse, mutect2, varscan2
- HECA | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV100866240; called by muse, mutect2, varscan2
- HECTD1 | c.5906C>T p.S1969F | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV67949048; called by muse, mutect2, varscan2
- HELZ2 | c.3928C>T p.P1310S (on ENST00000467148 / NM_001037335.2; = p.P741S on NM_033405.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71296742, COSV71296990; called by muse, varscan2
- HERC1 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV71250132; called by muse, mutect2, varscan2
- HERC2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55324706; called by muse, mutect2, varscan2
- HFM1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV54036876; called by muse, mutect2, varscan2
- HGFAC | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs750501405, COSV66976746; called by muse, mutect2, varscan2
- HIF3A | c.1661C>T p.P554L (on ENST00000377670 / NM_152795.4; = p.P485L on NM_022462.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52202900; called by muse, mutect2
- HIVEP1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 79/285 reads (28%) | catalogued as COSV65104468, COSV65104921; called by muse, mutect2, varscan2
- HJV | c.791C>T p.S264L (on ENST00000336751 / NM_213653.4; = p.S151L on NM_145277.5) | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.092); catalogued as rs782576713, COSV60953139; called by muse, mutect2, varscan2
- HLA-DRB1 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100750961, COSV63512576; called by muse, mutect2
- HMCN1 | c.10076C>T p.S3359L | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.993); catalogued as COSV54939634; called by muse, mutect2, varscan2
- HMGCLL1 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51451651; called by muse, mutect2, varscan2
- HMSD | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.406); catalogued as COSV68817083; called by muse, mutect2, varscan2
- HNF1B | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1209910423; called by muse, mutect2, varscan2
- HNF4A | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57388987; called by muse, mutect2, varscan2
- HNRNPM | c.601A>G p.R201G | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57694609; called by muse, mutect2, varscan2
- HOXB13 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1483360509, COSV51707165; called by muse, mutect2, varscan2
- HOXD10 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV50895289; called by muse, mutect2, varscan2
- HOXD3 | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0.374); catalogued as rs772793891, COSV50885305; called by muse, mutect2, varscan2
- HRNR | c.7538G>A p.G2513D | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as rs879841488, COSV100913723; called by mutect2, varscan2
- HSD17B4 | c.1648+2T>G p.X550_splice (on ENST00000414835 / NM_001199291.3; = p.X525_splice on NM_000414.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/59 reads (39%) | catalogued as COSV56338940; called by muse, mutect2, varscan2
- HTR1E | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs777916050, COSV59507236; called by muse, mutect2, varscan2
- HTT | c.8108C>T p.S2703F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV61866216; called by muse, mutect2, varscan2
- HYAL4 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56140355; called by muse, mutect2, varscan2
- HYDIN | c.9962C>T p.A3321V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66888858; called by muse, mutect2, varscan2
- HYDIN | c.7778G>A p.G2593E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV59269178; called by muse, varscan2
- HYDIN | c.7742G>A p.W2581* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV59269210; called by muse, varscan2
- HYDIN | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99864076; called by mutect2, varscan2
- HYOU1 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs1220649714, COSV68217312; called by muse, mutect2, varscan2
- ICAM4 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.143); catalogued as rs889667180, COSV53423143; called by muse, mutect2
- IFT172 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs371011000, COSV53131134; called by muse, mutect2, varscan2
- IGF1R | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51380338; called by muse, mutect2, varscan2
- IGF2BP1 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV51731960; called by muse, mutect2, varscan2
- IGKV1-16 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs2848410; called by muse, varscan2
- IGKV1-5 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs11546116; called by muse, mutect2
- IGLV2-8 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 162/211 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750475072; called by muse, mutect2, varscan2
- IGSF1 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 138/158 reads (87%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV63840172; called by muse, mutect2, varscan2
- IGSF1 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV63840179; called by muse, mutect2, varscan2
- IGSF3 | c.1478C>T p.S493L (on ENST00000369486 / NM_001007237.3; = p.S513L on NM_001542.4) | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.91); catalogued as rs752167211, COSV59598319; called by muse, mutect2, varscan2
- IL20RA | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV57360487; called by muse, mutect2
- IL31 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV65476707; called by muse, mutect2, varscan2
- IL36A | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV52083813; called by muse, mutect2, varscan2
- IL7R | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.059); catalogued as COSV57413161; called by muse, mutect2, varscan2
- IMMT | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755867536, COSV54479395; called by muse, mutect2, varscan2
- IMPG1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs371118175, COSV64056995; called by muse, mutect2, varscan2
- IMPG2 | c.1999T>C p.Y667H | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV51985459; called by muse, mutect2, varscan2
- INHBE | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV56989069; called by muse, mutect2, varscan2
- INO80D | c.2920C>T p.Q974* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV68960012; called by muse, mutect2, varscan2
- INSRR | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV63877114; called by muse, mutect2, varscan2
- IQCG | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 154/338 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV54566114; called by muse, mutect2, varscan2
- IQGAP2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769166078, COSV57181948; called by muse, mutect2, varscan2
- IQGAP2 | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV57181956; called by muse, mutect2, varscan2
- IQSEC3 | c.2440C>T p.R814* (on ENST00000538872 / NM_001170738.2; = p.R511* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as COSV58284083; called by muse, mutect2, varscan2
- IRF2BP1 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as COSV56195044; called by muse, mutect2, varscan2
- ITGA10 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100994629, COSV65199140; called by muse, mutect2, varscan2
- ITGA8 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV65235558; called by muse, mutect2, varscan2
- ITGA8 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV65227813, COSV65230571, COSV65235310; called by muse, mutect2, varscan2
- ITIH1 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs1447459532, COSV56258371; called by muse, mutect2, varscan2
- ITIH2 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as rs551693398, COSV64432040; called by muse, varscan2
- ITIH2 | c.2732G>A p.G911E | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1008244932, COSV64434558; called by muse, varscan2
- ITM2A | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 11/13 reads (85%) | catalogued as COSV64811619; called by muse, mutect2, varscan2
- ITPR1 | c.4000G>A p.E1334K (on ENST00000354582; = p.E1319K on NM_002222.7) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1339985150, COSV57002647; called by muse, mutect2, varscan2
- ITPR1 | c.6941G>A p.W2314* (on ENST00000354582; = p.W2259* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV57002667; called by muse, mutect2, varscan2
- ITPR2 | c.3187C>T p.H1063Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1268274667, COSV67275848; called by muse, mutect2, varscan2
- ITPRID1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV60082327; called by muse, mutect2, varscan2
- ITSN1 | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV67157624; called by muse, mutect2, varscan2
- JCAD | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773935496, COSV64760302; called by muse, mutect2, varscan2
- JPH1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); catalogued as COSV60614542; called by muse, mutect2, varscan2
- KAAG1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.116); catalogued as COSV51240085; called by muse, mutect2, varscan2
- KANK4 | c.1544G>A p.G515E | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV62989245; called by muse, mutect2, varscan2
- KAT6A | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs267601926, COSV55904555; called by muse, mutect2, varscan2
- KBTBD8 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as COSV55130899; called by muse, mutect2, varscan2
- KCNA6 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1423494168, COSV54974060; called by muse, mutect2, varscan2
- KCNB2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs866484467, COSV73051743; called by muse, mutect2, varscan2
- KCNG1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.66); PolyPhen probably damaging (1); catalogued as COSV65368966; called by muse, mutect2, varscan2
- KCNG1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100857136; called by muse, mutect2, varscan2
- KCNH6 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV59001356; called by muse, mutect2, varscan2
- KCNH7 | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59812878; called by muse, mutect2, varscan2
- KCNJ15 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60811941; called by muse, mutect2, varscan2
- KCNK1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64035433; called by muse, mutect2, varscan2
- KCNMA1 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54233723; called by muse, mutect2, varscan2
- KCNQ2 | c.2030G>A p.R677Q (on ENST00000359125 / NM_172107.4; = p.R649Q on NM_004518.6) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs1326189284, COSV60553136; called by muse, mutect2, varscan2
- KCNQ3 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101195692, COSV66475751; called by muse, mutect2, varscan2
- KCNQ4 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV61275659; called by muse, mutect2, varscan2
- KCNQ5 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100570644, COSV59649294; called by muse, mutect2, varscan2
- KCNT2 | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99655388; called by muse, mutect2, varscan2
- KCNT2 | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99655392, COSV99657221; called by muse, mutect2, varscan2
- KCTD14 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369578791; called by muse, mutect2, varscan2
- KDM4C | c.2870A>T p.Y957F | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV67192718; called by muse, mutect2, varscan2
- KDR | c.2701C>T p.L901F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55775680; called by muse, varscan2
- KEL | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs188645006, COSV62333334, COSV62335963; called by muse, mutect2, varscan2
- KEL | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as COSV62337742; called by muse, mutect2, varscan2
- KHDRBS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs868714236, COSV55428923; called by muse, mutect2, varscan2
- KHDRBS2 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV55430948; called by muse, mutect2
- KIAA0100 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV66496214; called by muse, mutect2
- KIAA1109 | c.14113C>T p.H4705Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.486); catalogued as COSV52691264; called by muse, mutect2, varscan2
- KIAA1549 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54327575; called by muse, mutect2, varscan2
- KIAA1549L | c.971C>T p.P324L (on ENST00000321505; = p.P621L on NM_012194.3) | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV55779127; called by muse, mutect2, varscan2
- KIAA1755 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 48/121 reads (40%) | catalogued as COSV54080474; called by muse, mutect2, varscan2
- KIF15 | c.3997G>A p.V1333M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV58164634; called by muse, mutect2, varscan2
- KIF1B | c.913C>T p.P305S (on ENST00000377086 / NM_001365952.1; = p.P299S on NM_015074.3) | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55813075; called by muse, mutect2, varscan2
- KIF20B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53308847; called by muse, mutect2, varscan2
- KIF5A | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV54058977; called by muse, mutect2, varscan2
- KL | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.207); catalogued as rs750131236, COSV66310006; called by muse, mutect2, varscan2
- KLKB1 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV52999224; called by muse, mutect2, varscan2
- KMO | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs764174100, COSV63810591; called by muse, mutect2, varscan2
- KNDC1 | c.4304C>T p.T1435I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV58845847; called by muse, mutect2, varscan2
- KRR1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56991076; called by muse, mutect2, varscan2
- KRT10 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV54091485; called by muse, mutect2, varscan2
- KRT15 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV54181826; called by muse, mutect2, varscan2
- KRT23 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as COSV52928951; called by muse, mutect2, varscan2
- KRT71 | c.837C>A p.H279Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as COSV57292921; called by muse, mutect2, varscan2
- KRT78 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766560029, COSV58853498; called by muse, mutect2, varscan2
- KRT83 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV53342561; called by muse, mutect2, varscan2
- KRTAP5-5 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV68785716; called by muse, varscan2
- L1CAM | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 72/80 reads (90%) | catalogued as COSV100649352; called by muse, mutect2, varscan2
- L3MBTL4 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV53139718; called by muse, mutect2
- LAMA2 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV70354701; called by muse, mutect2, varscan2
- LAMA2 | c.3913G>A p.E1305K | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.871); catalogued as COSV70354704; called by muse, mutect2, varscan2
- LAMB3 | c.3230G>A p.G1077E | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.274); catalogued as COSV50526141; called by muse, mutect2, varscan2
- LAMB3 | c.3037G>A p.D1013N | Missense Mutation (SNP) | VAF 76/126 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV50526142; called by muse, mutect2, varscan2
- LAMB4 | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV52718714; called by muse, mutect2, varscan2
- LARS2 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs755162646, COSV55531942; called by muse, mutect2, varscan2
- LCE3E | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 117/188 reads (62%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs1308992037, COSV64232266; called by muse, mutect2, varscan2
- LCN9 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52992516; called by muse, mutect2, varscan2
- LDB2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs1480863984, COSV100453424, COSV58766987; called by muse, varscan2
- LGALS13 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV55680814; called by muse, mutect2, varscan2
- LGI1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65059218; called by muse, mutect2, varscan2
- LGSN | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as rs749416344, COSV65728581; called by muse, mutect2, varscan2
- LHCGR | c.1970C>T p.S657L | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV54302817; called by muse, mutect2, varscan2
- LILRA1 | c.1171C>T p.H391Y | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV99252020; called by muse, mutect2, varscan2
- LILRA4 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52494568; called by muse, mutect2, varscan2
- LILRA6 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV99558753; called by muse, mutect2, varscan2
- LINGO2 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as rs756489081, COSV58061284; called by muse, mutect2, varscan2
- LIPI | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60715941; called by muse, mutect2, varscan2
- LIPN | c.1036C>T p.L346F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.728); catalogued as COSV68384503; called by muse, mutect2, varscan2
- LMX1A | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs768850154, COSV54225152; called by muse, mutect2, varscan2
- LNX1 | c.1571G>A p.G524E (on ENST00000263925 / NM_001126328.3; = p.G428E on NM_032622.2) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750425165, COSV55791470; called by muse, mutect2, varscan2
- LOXL2 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV66693440, COSV66694197; called by muse, mutect2, varscan2
- LPA | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 140/405 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60311532; called by muse, mutect2, varscan2
- LPCAT2 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.11); catalogued as COSV50895309; called by muse, mutect2, varscan2
- LRFN3 | c.62A>T p.Q21L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55819052; called by muse, mutect2, varscan2
- LRGUK | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53643479; called by muse, mutect2, varscan2
- LRP1B | c.5975C>T p.S1992F | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67209148; called by muse, mutect2, varscan2
- LRP1B | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs868652515, COSV67213914; called by muse, mutect2, varscan2
- LRP2 | c.13853C>T p.S4618L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs142430940; called by muse, mutect2, varscan2
- LRP2 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as COSV55573248; called by muse, mutect2, varscan2
- LRP4 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66138589; called by muse, mutect2, varscan2
- LRRC4C | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV53423535, COSV53437516; called by muse, mutect2, varscan2
- LRRK1 | c.4096dup p.I1366Nfs*21 | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | catalogued as rs1567274364; called by mutect2, pindel, varscan2
- LY86 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57913871; called by muse, mutect2
- LZTR1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV53151546; called by muse, mutect2, varscan2
- LZTS1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56118410; called by muse, mutect2, varscan2
- MAGEA11 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 66/77 reads (86%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs782156874, COSV60758474; called by muse, mutect2, varscan2
- MAGEC1 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 89/94 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV53573608, COSV53580961; called by muse, mutect2, varscan2
- MAGEC1 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 180/217 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV53577923, COSV53580970; called by muse, mutect2, varscan2
- MAGEC1 | c.2755C>T p.L919F | Missense Mutation (SNP) | VAF 134/160 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53577213, COSV53580984; called by muse, mutect2, varscan2
- MAGEC2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56001365; called by muse, mutect2, varscan2
- MAJIN | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV54164950; called by muse, mutect2, varscan2
- MAML1 | c.1512T>A p.N504K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as COSV52988622; called by muse, mutect2, varscan2
- MAN1A1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs774209358, COSV63782664; called by muse, mutect2, varscan2
- MAN2B2 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53452986; called by muse, mutect2, varscan2
- MAP1A | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55812370; called by muse, mutect2, varscan2
- MAP1A | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as rs758079886, COSV55812379; called by muse, mutect2, varscan2
- MAP3K11 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58420753; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV53799796; called by muse, mutect2, varscan2
- MARVELD3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV51705776; called by muse, varscan2
- MARVELD3 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51705904; called by muse, varscan2
- MASP1 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs140271320; called by muse, varscan2
- MATN4 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV59215682; called by muse, mutect2, varscan2
- MAVS | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs999261113, COSV63927596; called by muse, mutect2, varscan2
- MBD5 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68698885; called by muse, mutect2, varscan2
- MCCC2 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100039958, COSV60156809; called by muse, mutect2, varscan2
- MCF2 | c.574T>C p.L192= | Splice Region (SNP) | VAF 30/37 reads (81%) | catalogued as COSV58494686; called by muse, mutect2, varscan2
- MCF2L | c.2075A>T p.H692L (on ENST00000375608; = p.H660L on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56181361; called by mutect2, varscan2
- MCHR2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56000050, COSV56003328; called by muse, mutect2, varscan2
- MCM5 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.349); catalogued as COSV53348161, COSV99332126; called by muse, mutect2, varscan2
- MCMDC2 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58040879; called by muse, mutect2, varscan2
- MDGA1 | c.2669T>A p.I890N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV51801569; called by muse, mutect2, varscan2
- ME2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs755264666, COSV58424947; called by muse, mutect2, varscan2
- MECOM | c.518C>T p.S173L (on ENST00000468789 / NM_001105078.4; = p.S361L on NM_004991.4) | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52974076; called by muse, mutect2, varscan2
- MED12L | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56370234, COSV99851498; called by muse, mutect2, varscan2
- MED27 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV52605862; called by muse, mutect2, varscan2
- MEF2D | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV61730326; called by muse, mutect2, varscan2
- MEFV | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as rs368981831; called by muse, mutect2, varscan2
- MEIS2 | c.808C>T p.P270S (on ENST00000561208 / NM_170675.5; = p.P257S on NM_002399.3) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.222); catalogued as COSV54944399; called by muse, mutect2, varscan2
- MEP1A | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57922421; called by muse, mutect2, varscan2
- MGAM | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV71886053; called by muse, mutect2, varscan2
- MIA2 | c.1673C>T p.T558I | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV54486222; called by muse, mutect2, varscan2
- MICALL2 | c.1805+2T>C p.X602_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV52518709; called by muse, mutect2, varscan2
- MINAR1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59586341; called by muse, mutect2, varscan2
- MINAR1 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV59586349; called by muse, mutect2, varscan2
- MITF | c.891A>C p.R297S (on ENST00000448226 / NM_006722.3; = p.R197S on NM_000248.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58835705; called by muse, mutect2, varscan2
- MKS1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV58306147; called by muse, mutect2, varscan2
- MLIP | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51434593; called by muse, mutect2, varscan2
- MME | c.521G>A p.W174* | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100852421, COSV64710678; called by muse, mutect2, varscan2
- MMP21 | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV64290328; called by muse, mutect2, varscan2
- MMP26 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs371700941, COSV56171675; called by muse, mutect2, varscan2
- MMRN1 | c.3428G>A p.G1143E | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766488356, COSV53342341; called by muse, mutect2, varscan2
- MPP4 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59634319; called by muse, mutect2, varscan2
- MPP7 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs1329732354, COSV61737896; called by muse, mutect2, varscan2
- MRGPRX3 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1564882283, COSV66933179; called by muse, mutect2, varscan2
- MSANTD3 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.935); catalogued as COSV58497320; called by muse, mutect2, varscan2
- MSH5 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV65211510; called by muse, mutect2, varscan2
- MSLNL | c.1982G>A p.G661E | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV53506160; called by muse, mutect2, varscan2
- MSR1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50523234; called by muse, mutect2, varscan2
- MT3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99570528; called by muse, mutect2, varscan2
- MTA2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV53471948; called by muse, mutect2, varscan2
- MTCL1 | c.3365C>T p.T1122I (on ENST00000306329 / NM_001378206.1; = p.T803I on NM_015210.4) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV60411571; called by muse, mutect2, varscan2
- MTF1 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.709); catalogued as rs1002700894, COSV65990607; called by muse, mutect2, varscan2
- MTMR12 | c.1474T>G p.F492V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53787799; called by muse, mutect2, varscan2
- MTMR4 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.241); catalogued as COSV60203618; called by muse, mutect2, varscan2
- MTUS2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV70920161; called by muse, mutect2, varscan2
- MUC16 | c.42277G>A p.G14093S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (0.997); catalogued as rs1396582542, COSV66696225; called by muse, mutect2, varscan2
- MUC16 | c.39391C>T p.R13131W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs374713531; called by muse, mutect2, varscan2
- MUC16 | c.32026G>A p.E10676K | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as COSV67491904; called by muse, mutect2, varscan2
- MUC16 | c.30671C>T p.P10224L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.917); catalogued as rs1276052059, COSV101200526; called by muse, mutect2, varscan2
- MUC16 | c.30670C>T p.P10224S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV67467155; called by muse, mutect2, varscan2
- MUC16 | c.21869C>T p.S7290F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.109); catalogued as rs1479427786, COSV67447658, COSV67494696; called by muse, mutect2, varscan2
- MUC16 | c.18616G>A p.D6206N | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV67491923; called by muse, mutect2, varscan2
- MUC16 | c.12548C>T p.P4183L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV67491927; called by muse, mutect2, varscan2
- MUC16 | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV67491935; called by muse, mutect2, varscan2
- MUC21 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 301/496 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1460581232, COSV66222180; called by muse, mutect2, varscan2
- MUC5B | c.2705A>G p.H902R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71595315; called by muse, mutect2, varscan2
- MUC5B | c.5092G>A p.A1698T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV71595319; called by muse, mutect2
- MYF5 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57354993; called by muse, mutect2, varscan2
- MYF6 | c.54A>T p.E18D | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV57353254; called by muse, mutect2, varscan2
1,503 further variants in this file (718 protein-altering or splice-affecting, 731 silent, 54 other) are not listed here.
